Somatic mutation profile of tumor specimen MP2PRT-PATTRU-TMP1-A (aliquot MP2PRT-PATTRU-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATTRU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (695 days).
Specimen MP2PRT-PATTRU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25bc62a9-d651-47dd-905e-7a3068401627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATTRU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATTRU-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53b38968-ef67-4304-8160-1b7ee36becba

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 4, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 33/233 reads (14%) | catalogued as rs886041116, CM166963, COSV100823721; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNTN3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 131/364 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367688857; called by muse, mutect2, varscan2
- CSE1L | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs753618454, COSV53700874; called by muse, mutect2, varscan2
- DRD1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs182894202; called by muse, mutect2
- FAM135A | c.1037G>A p.R346K (on ENST00000370479 / NM_001351599.1; = p.R329K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99526516; called by muse, mutect2, varscan2
- FAM83B | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs778588613, COSV100173938, COSV100174318, COSV60920027; called by muse, mutect2, varscan2
- OPA3 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 54/581 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs558412882; called by muse, mutect2
- PDZD7 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 172/674 reads (26%) | catalogued as rs771079550; called by muse, mutect2, varscan2
- PLPPR4 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 17/305 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV100926757; called by muse, mutect2
- RSPO1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 100/461 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs374906144, COSV100740463; called by muse, mutect2, varscan2
- BIRC6 | c.11588C>G p.S3863* | Nonsense Mutation (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2, varscan2
- CROCC2 | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); called by muse, mutect2
- DNAH6 | c.7273G>A p.A2425T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM189A1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 35/503 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- GALNT9 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 20/547 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2
- IGHV1-46 | c.350_351insGGACCGGCGGTTCCAG p.*118Dfs*? | Frame Shift Ins (INS) | VAF 20/147 reads (14%) | called by mutect2, pindel, varscan2
- IL23A | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 134/345 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- NR3C1 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TCHH | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 108/365 reads (30%) | called by muse, mutect2, varscan2
- ZFP37 | c.1785C>A p.H595Q | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALPK3 | c.3402C>A p.A1134= | Silent (SNP) | VAF 171/487 reads (35%) | called by muse, mutect2, varscan2
- GABBR1 | c.2064C>T p.V688= | Silent (SNP) | VAF 60/585 reads (10%) | called by muse, mutect2
- GGACT | c.309G>A p.P103= | Silent (SNP) | VAF 60/528 reads (11%) | catalogued as rs1369080588, COSV100883501, COSV66157602; called by muse, mutect2, varscan2
- GRM1 | c.861G>A p.V287= | Silent (SNP) | VAF 102/374 reads (27%) | called by muse, mutect2, varscan2
- MEIS2 | c.123C>T p.H41= (on ENST00000561208 / NM_170675.5; = p.H28= on NM_002399.3) | Silent (SNP) | VAF 160/629 reads (25%) | catalogued as COSV54939102; called by muse, mutect2, varscan2
- MYH7 | c.396G>A p.P132= | Silent (SNP) | VAF 101/381 reads (27%) | catalogued as rs138932714; ClinVar: likely benign; called by muse, mutect2, varscan2
- SF3A2 | c.564C>T p.I188= | Silent (SNP) | VAF 33/607 reads (5%) | catalogued as rs567913695, COSV99677985; called by muse, mutect2
- TCHH | c.1650G>C p.L550= | Silent (SNP) | VAF 117/457 reads (26%) | called by muse, mutect2, varscan2
- GJC1 | chr17:44830688 C>G | 5'Flank (SNP) | VAF 47/445 reads (11%) | called by muse, mutect2, varscan2
